Somatic mutation profile of tumor specimen ALCH-ADW6-TTP1-A (aliquot ALCH-ADW6-TTP1-A-1-0-D-A587-36) from ALCHEMIST case ALCH-ADW6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.5 years (23,564 days).
Specimen ALCH-ADW6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4434732-a5cc-48e6-959d-d68801cb4866.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADW6-NB1-A (Blood Derived Normal), aliquot ALCH-ADW6-NB1-A-1-0-D-A587-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b1e37f8-c8e7-447f-b4ee-d09f9bd62553

The open-access MAF lists 499 somatic variants for this specimen: 341 protein-altering or splice-affecting, 93 silent, 65 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 301, Silent 93, Intron 35, Nonsense Mutation 24, RNA 9, 3'UTR 7, 5'UTR 7, Splice Site 6, Frame Shift Del 5, 5'Flank 5, Splice Region 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1E | c.661C>G p.L221V | Missense Mutation (SNP) | VAF 19/223 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as rs1553286278; ClinVar: likely pathogenic; called by muse, mutect2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 90/545 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 80/682 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACAN | c.1697C>T p.T566I | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs759458195; called by muse, mutect2, varscan2
- AGAP3 | c.1933G>T p.D645Y (on ENST00000622464; = p.D681Y on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV68243749; called by muse, mutect2, varscan2
- AGXT2 | c.761G>T p.C254F | Missense Mutation (SNP) | VAF 94/651 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51484195; called by muse, mutect2, varscan2
- AHNAK2 | c.13170G>T p.K4390N | Missense Mutation (SNP) | VAF 46/368 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60908461; called by muse, mutect2, varscan2
- AKR1E2 | c.399G>T p.L133F | Missense Mutation (SNP) | VAF 38/475 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs770991583; called by muse, mutect2
- ALPL | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66376493; called by muse, mutect2
- AMHR2 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 38/574 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769446870; called by muse, mutect2
- ANKRD39 | c.107G>T p.W36L | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.315); catalogued as rs1298645141; called by muse, mutect2, varscan2
- AP002512.3 | c.1033G>T p.G345W | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs773549534; called by muse, mutect2
- APBA3 | c.111G>T p.W37C | Missense Mutation (SNP) | VAF 48/295 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV100349665; called by muse, mutect2, varscan2
- ATP8B4 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99466802; called by muse, mutect2, varscan2
- C1QA | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 80/618 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV65889943; called by muse, mutect2, varscan2
- C1orf146 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1464407091; called by muse, mutect2
- CCT8L2 | c.389C>A p.P130Q | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.181); catalogued as rs754994430; called by muse, mutect2, varscan2
- CFTR | c.1488G>A p.W496* | Nonsense Mutation (SNP) | VAF 55/415 reads (13%) | catalogued as rs200626971; called by muse, mutect2, varscan2
- CLCA4 | c.1424C>A p.A475D | Missense Mutation (SNP) | VAF 51/467 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs1339868601; called by muse, mutect2, varscan2
- CNTNAP5 | c.548T>C p.F183S | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV70484195; called by muse, mutect2
- COL17A1 | c.791C>A p.A264E | Missense Mutation (SNP) | VAF 106/720 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV62227027; called by muse, varscan2
- COLGALT2 | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62299055; called by muse, mutect2
- CSAG1 | c.200C>A p.P67H | Missense Mutation (SNP) | VAF 65/344 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100767465; called by muse, mutect2, varscan2
- CT47B1 | c.662A>T p.E221V | Missense Mutation (SNP) | VAF 106/755 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs1281170202; called by muse, mutect2, varscan2
- CTCF | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 30/457 reads (7%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.007); catalogued as COSV50519222; called by muse, mutect2
- CTNNA2 | c.1514C>G p.S505* | Nonsense Mutation (SNP) | VAF 26/261 reads (10%) | catalogued as COSV58143442, COSV58154065; called by muse, mutect2, varscan2
- DLGAP3 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 29/459 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs768529358, COSV52395331; called by muse, mutect2
- DNAH11 | c.7812G>T p.W2604C | Missense Mutation (SNP) | VAF 60/446 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60971493; called by muse, varscan2
- EPHA10 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as COSV104397424; called by muse, mutect2, varscan2
- EPX | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 74/361 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV56595369; called by muse, mutect2, varscan2
- ERBB3 | c.1813G>C p.D605H | Missense Mutation (SNP) | VAF 29/424 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs1177447452; called by muse, mutect2
- ERICH3 | c.3787G>T p.G1263* | Nonsense Mutation (SNP) | VAF 75/568 reads (13%) | catalogued as COSV58617355; called by muse, mutect2, varscan2
- FAM170B | c.92G>A p.S31N | Missense Mutation (SNP) | VAF 45/323 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV99043382; called by muse, mutect2, varscan2
- FAM71E2 | c.664C>A p.R222S | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs780260883; called by muse, mutect2, varscan2
- FANCI | c.3004C>G p.Q1002E (on ENST00000310775 / NM_001376911.1; = p.Q942E on NM_018193.3) | Missense Mutation (SNP) | VAF 58/672 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs1384513899; called by muse, mutect2
- FHL5 | c.833C>A p.S278Y | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV58741448; called by muse, mutect2, varscan2
- FLG | c.12167G>C p.R4056T | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV64249205; called by muse, mutect2
- FLT3 | c.2545C>A p.R849S | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs959896930; called by muse, mutect2, varscan2
- FOXI3 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1451029499, COSV101230982; called by muse, mutect2
- FPGT-TNNI3K | c.1670C>A p.A557E | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs774773030; called by muse, mutect2, varscan2
- GAREM2 | c.1873G>A p.A625T | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV66108353; called by muse, mutect2, varscan2
- GKN1 | c.552G>C p.E184D | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV65006496; called by muse, mutect2
- HDC | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 120/793 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.292); catalogued as COSV99983740; called by muse, mutect2, varscan2
- HNF1B | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 52/623 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1024639436; ClinVar: uncertain significance; called by muse, mutect2
- HOXA3 | c.776C>A p.S259* | Nonsense Mutation (SNP) | VAF 29/203 reads (14%) | catalogued as COSV57829517; called by muse, mutect2, varscan2
- IGSF1 | c.3557C>T p.P1186L | Missense Mutation (SNP) | VAF 34/499 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63839499; called by muse, mutect2
- IRF2BPL | c.2306C>T p.S769L | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1228949187, COSV53146577; called by muse, mutect2, varscan2
- KIF2B | c.1993G>T p.D665Y | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as COSV99082062; called by muse, mutect2, varscan2
- KRT82 | c.1295G>A p.C432Y | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs771754920; called by muse, mutect2
- LIN52 | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as rs746514417; called by muse, mutect2, varscan2
- LINGO2 | c.486C>A p.D162E | Missense Mutation (SNP) | VAF 45/362 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.863); catalogued as rs775438948, COSV58056709; called by muse, mutect2, varscan2
- LIPM | c.1084C>A p.P362T | Missense Mutation (SNP) | VAF 30/451 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.567); catalogued as rs1488165850; called by muse, mutect2
- LRFN5 | c.379C>A p.H127N | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53244329; called by muse, mutect2, varscan2
- LRRTM4 | c.1214C>A p.S405Y | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs1386387121, COSV69141710; called by muse, mutect2
- MAML2 | c.3248C>T p.T1083M | Missense Mutation (SNP) | VAF 25/288 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.65); catalogued as rs370201127; called by muse, mutect2
- MAP2 | c.4468G>C p.A1490P | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1371982188; called by muse, mutect2, varscan2
- MMP14 | c.1138G>T p.V380F | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV61288874; called by muse, mutect2, varscan2
- MORC1 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 22/422 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1453242500, COSV51716702; called by muse, mutect2
- MS4A1 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 46/540 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV61942312; called by muse, mutect2
- MTUS2 | c.3646G>C p.A1216P (on ENST00000612955 / NM_001366650.1; = p.A195P on NM_015233.6) | Missense Mutation (SNP) | VAF 47/326 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101070818, COSV66422671; called by muse, mutect2, varscan2
- MYO15B | c.4192G>A p.D1398N | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs893414998; called by muse, mutect2
- MYOG | c.430C>A p.R144S | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.097); catalogued as COSV99614171; called by muse, mutect2
- NAGS | c.1523T>C p.I508T | Missense Mutation (SNP) | VAF 83/716 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1416694151; called by muse, mutect2, varscan2
- NELL1 | c.2407G>T p.D803Y | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54241447, COSV54277311; called by muse, mutect2, varscan2
- NFASC | c.1499C>A p.T500N (on ENST00000339876 / NM_001378329.1; = p.T511N on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/503 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs1281353967, COSV58365906; called by muse, mutect2, varscan2
- NPBWR1 | c.891C>G p.Y297* | Nonsense Mutation (SNP) | VAF 21/325 reads (6%) | catalogued as COSV58695497, COSV58697662; called by muse, mutect2
- OR10G7 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57865600, COSV57868499; called by muse, mutect2
- OR2F2 | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 24/542 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.031); catalogued as COSV101283789; called by muse, mutect2
- OR2G2 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.095); catalogued as rs1285366956; called by muse, mutect2, varscan2
- OR2M2 | c.852G>C p.M284I | Missense Mutation (SNP) | VAF 113/566 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as COSV100677237; called by muse, mutect2, varscan2
- OR2T6 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV63216271; called by muse, mutect2, varscan2
- OR4C15 | c.325G>T p.V109L (on ENST00000314644; = p.V55L on NM_001001920.2) | Missense Mutation (SNP) | VAF 59/358 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs771166464; called by muse, mutect2, varscan2
- OR4K15 | c.926T>C p.V309A (on ENST00000305051; = p.V285A on NM_001005486.1) | Missense Mutation (SNP) | VAF 48/484 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV59303509; called by muse, mutect2
- PDHB | c.1025C>G p.S342C | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.167); catalogued as rs777056005; called by muse, mutect2
- PDILT | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 25/311 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs369365786, COSV100199895; called by muse, mutect2
- PLCB4 | c.1466del p.P489Qfs*5 | Frame Shift Del (DEL) | VAF 94/651 reads (14%) | catalogued as COSV53803755; called by mutect2, pindel, varscan2
- PLK2 | c.1438C>G p.R480G | Missense Mutation (SNP) | VAF 243/768 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV57106588; called by muse, mutect2, varscan2
- POLM | c.931C>G p.P311A | Missense Mutation (SNP) | VAF 15/210 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV54242594; called by muse, mutect2
- PPARG | c.93G>T p.M31I (on ENST00000287820 / NM_015869.5; = p.M1? on NM_005037.7) | Missense Mutation (SNP) | VAF 42/404 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs1335787704; called by muse, mutect2, varscan2
- PRORP | c.1474C>T p.H492Y | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs763715708; called by muse, mutect2, varscan2
- PRUNE2 | c.2620G>T p.D874Y | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV65043523, COSV65046681; called by muse, mutect2
- PSKH2 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 55/316 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV99405349; called by muse, mutect2, varscan2
- PXDNL | c.3301C>A p.L1101I | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV62497693; called by muse, mutect2
- QPRT | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs367579558; called by muse, mutect2, varscan2
- RGPD4 | c.4114G>C p.G1372R | Missense Mutation (SNP) | VAF 36/780 reads (5%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.945); catalogued as rs775032792; called by muse, mutect2
- RMND5A | c.777G>T p.W259C | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52154726; called by muse, mutect2
- RTL1 | c.2296G>C p.D766H | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV101128107; called by muse, mutect2
- S1PR1 | c.735C>A p.S245R | Missense Mutation (SNP) | VAF 41/357 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.555); catalogued as COSV59514912; called by muse, mutect2, varscan2
- SCN11A | c.3430A>T p.K1144* | Nonsense Mutation (SNP) | VAF 49/387 reads (13%) | catalogued as rs1553633898; called by muse, mutect2, varscan2
- SLC12A3 | c.1165A>G p.I389V | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.029); catalogued as rs756678250; called by muse, mutect2
- SLC8A3 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 59/369 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as COSV63525114; called by muse, mutect2, varscan2
- SLITRK1 | c.1260G>T p.K420N | Missense Mutation (SNP) | VAF 137/798 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV65674192; called by muse, mutect2, varscan2
- SMC3 | c.2387G>C p.R796T | Missense Mutation (SNP) | VAF 22/558 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV62418835; called by muse, mutect2
- SORCS1 | c.2596C>G p.R866G | Missense Mutation (SNP) | VAF 39/355 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV53858615; called by muse, mutect2, varscan2
- SRMS | c.254del p.G85Afs*119 | Frame Shift Del (DEL) | VAF 29/188 reads (15%) | catalogued as COSV53922142; called by pindel, varscan2
- TBRG4 | c.1865G>T p.R622L | Missense Mutation (SNP) | VAF 42/333 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as rs776622833, COSV51832961; called by muse, mutect2, varscan2
- TNFRSF19 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 28/424 reads (7%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.046); catalogued as rs1272150249; called by muse, mutect2
- TRAF3IP3 | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 36/593 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50551130; called by muse, mutect2
- TRIOBP | c.6416G>T p.R2139L (on ENST00000644935 / NM_001039141.3; = p.R426L on NM_007032.5) | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV60376235; called by muse, mutect2, varscan2
- UGGT2 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 13/338 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1217150159, COSV65025544; called by muse, mutect2
- UNC79 | c.1603C>A p.H535N (on ENST00000393151 / NM_001346218.2; = p.H358N on NM_020818.5) | Missense Mutation (SNP) | VAF 34/560 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.573); catalogued as COSV56392041; called by muse, mutect2
- VCAN | c.3928C>G p.P1310A | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV54097709; called by muse, mutect2, varscan2
- VCPIP1 | c.3388G>C p.E1130Q | Missense Mutation (SNP) | VAF 19/360 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.885); catalogued as rs1455504129; called by muse, mutect2
- XIRP2 | c.1886G>A p.G629E (on ENST00000628543; = p.G804E on NM_152381.6) | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.092); catalogued as rs760551633, COSV99744735; called by muse, mutect2
- XIRP2 | c.9365G>T p.R3122L (on ENST00000628543; = p.R3297L on NM_152381.6) | Missense Mutation (SNP) | VAF 56/413 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as rs777053988, COSV54691253; called by muse, mutect2, varscan2
- ZBTB24 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 40/625 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV57781780; called by muse, mutect2
- ZFHX4 | c.10787C>G p.A3596G | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.933); catalogued as COSV50488913; called by muse, mutect2, varscan2
- ZNF679 | c.586G>T p.V196F | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs765013726, COSV55377594; called by muse, mutect2, varscan2
- ZSWIM2 | c.1408C>A p.L470I | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.203); catalogued as COSV99720633; called by muse, mutect2
- ABCA13 | c.13529T>G p.F4510C | Missense Mutation (SNP) | VAF 40/342 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACSM1 | c.529T>A p.S177T | Missense Mutation (SNP) | VAF 53/459 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ADAD1 | c.1186G>T p.G396C | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- ADAD1 | c.1187G>T p.G396V | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAM11 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 51/365 reads (14%) | called by muse, mutect2, varscan2
- ADAM19 | c.1929C>A p.C643* | Nonsense Mutation (SNP) | VAF 55/435 reads (13%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.3273C>G p.I1091M | Missense Mutation (SNP) | VAF 82/518 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- ADAMTS12 | c.2288G>T p.G763V | Missense Mutation (SNP) | VAF 100/738 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADAMTS4 | c.865C>A p.L289M | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTSL3 | c.345C>G p.Y115* | Nonsense Mutation (SNP) | VAF 17/170 reads (10%) | called by muse, mutect2
- ADD1 | c.530A>C p.Q177P | Missense Mutation (SNP) | VAF 41/224 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ADGRF2 | c.1608G>T p.M536I (on ENST00000296862 / NM_001368115.2; = p.M468I on NM_153839.7) | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADGRL3 | c.3823G>A p.A1275T | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); called by muse, varscan2
- ADHFE1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 40/538 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.068); called by muse, mutect2
- AHNAK | c.13916C>G p.P4639R | Missense Mutation (SNP) | VAF 24/371 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALG2 | c.742G>T p.V248L | Missense Mutation (SNP) | VAF 50/415 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ALPK2 | c.1442G>T p.S481I | Missense Mutation (SNP) | VAF 42/371 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AMPD1 | c.315-1G>A p.X105_splice | Splice Site (SNP) | VAF 42/696 reads (6%) | called by muse, mutect2
- AOX1 | c.2258T>G p.M753R | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ARHGAP6 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ASPA | c.527-1G>T p.X176_splice | Splice Site (SNP) | VAF 25/259 reads (10%) | called by muse, mutect2
- ASTN1 | c.900G>T p.K300N | Missense Mutation (SNP) | VAF 45/417 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- BMP2 | c.1079G>T p.C360F | Missense Mutation (SNP) | VAF 94/552 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BMS1 | c.2029G>C p.E677Q | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.03); called by muse, mutect2
- BMT2 | c.19G>T p.G7C | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- BTNL8 | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 143/510 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- C19orf12 | c.225G>T p.W75C (on ENST00000392278 / NM_001031726.3; = p.W64C on NM_031448.6) | Missense Mutation (SNP) | VAF 104/786 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- C1orf94 | c.1739G>T p.G580V (on ENST00000488417 / NM_001134734.2; = p.G390V on NM_032884.5) | Missense Mutation (SNP) | VAF 29/301 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- C20orf194 | c.1222G>T p.G408W | Missense Mutation (SNP) | VAF 68/400 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- C8A | c.1231A>T p.R411W | Missense Mutation (SNP) | VAF 57/464 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- CACNA1I | c.3376C>A p.L1126M | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.851); called by muse, mutect2
- CACNA1S | c.1132G>T p.V378F | Missense Mutation (SNP) | VAF 159/821 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- CALY | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 40/567 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.356); called by muse, mutect2
- CAPN11 | c.1846C>A p.R616S | Missense Mutation (SNP) | VAF 61/390 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CCDC168 | c.8900G>C p.R2967T | Missense Mutation (SNP) | VAF 48/307 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- CCDC189 | c.610A>T p.T204S | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CD4 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 17/322 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); called by muse, mutect2
- CDC14C | c.850C>A p.H284N (on ENST00000428251; = p.H177N on NM_152627.3) | Missense Mutation (SNP) | VAF 31/492 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.133); called by muse, mutect2
- CDH17 | c.1636A>T p.N546Y | Missense Mutation (SNP) | VAF 94/522 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDH9 | c.2307C>A p.D769E | Missense Mutation (SNP) | VAF 77/226 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- CELA1 | c.26C>A p.T9N | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CERS3 | c.260T>C p.F87S | Missense Mutation (SNP) | VAF 47/291 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- CFAP65 | c.2637G>T p.K879N | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- CHUK | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 54/346 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CILP | c.2357T>A p.F786Y | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CLCN1 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 114/696 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- CLCN1 | c.448del p.Y150Tfs*20 | Frame Shift Del (DEL) | VAF 73/703 reads (10%) | called by mutect2, pindel, varscan2
- CNTNAP4 | c.2366-2A>G p.X789_splice | Splice Site (SNP) | VAF 34/246 reads (14%) | called by mutect2, varscan2
- COL14A1 | c.4878G>T p.Q1626H | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- COL7A1 | c.6983C>A p.A2328D | Missense Mutation (SNP) | VAF 36/562 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.398); called by muse, mutect2
- CRAT | c.1275G>C p.E425D | Missense Mutation (SNP) | VAF 14/271 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2
- CRISP3 | c.196C>A p.Q66K (on ENST00000371159 / NM_001368123.1; = p.Q48K on NM_006061.4) | Missense Mutation (SNP) | VAF 30/604 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- CSMD3 | c.1063G>T p.G355C | Missense Mutation (SNP) | VAF 83/496 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CT45A10 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 36/426 reads (8%) | SIFT tolerated (0.85); PolyPhen benign (0.007); called by muse, mutect2
- CYCS | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 109/729 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- DCAF11 | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 38/249 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DCAF5 | c.711G>C p.M237I | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.204); called by muse, mutect2
- DCSTAMP | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 68/394 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- DDI1 | c.865G>C p.V289L | Missense Mutation (SNP) | VAF 44/291 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DHX16 | c.1764G>T p.E588D | Missense Mutation (SNP) | VAF 57/197 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EBF2 | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- EFR3B | c.1206G>T p.M402I | Missense Mutation (SNP) | VAF 20/253 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2
- EIF3D | c.1507G>T p.E503* | Nonsense Mutation (SNP) | VAF 66/669 reads (10%) | called by muse, mutect2
- EIF4ENIF1 | c.1858C>G p.L620V | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EML1 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- EPB41 | c.1121A>T p.Y374F (on ENST00000343067 / NM_001166005.2; = p.Y165F on NM_004437.4) | Missense Mutation (SNP) | VAF 52/524 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.233); called by muse, mutect2
- EPPK1 | c.2533G>T p.G845C | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- EPPK1 | c.2532G>T p.E844D | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ERMARD | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2
- F13A1 | c.1369G>T p.D457Y | Missense Mutation (SNP) | VAF 126/634 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FADS6 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 66/470 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FAHD1 | c.645G>C p.M215I | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.054); called by muse, mutect2
- FAM120AOS | c.146T>A p.L49Q | Missense Mutation (SNP) | VAF 31/315 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FAM153A | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); called by mutect2, varscan2
- FAM160B1 | c.784G>T p.V262L | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- FAM9A | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 14/219 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); called by muse, mutect2
- FBXO15 | c.226G>C p.G76R | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FCGBP | c.721C>A p.Q241K | Missense Mutation (SNP) | VAF 74/346 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FGF2 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- FLNC | c.7898C>G p.S2633* | Nonsense Mutation (SNP) | VAF 26/654 reads (4%) | called by muse, mutect2
- FRMPD4 | c.38C>A p.S13* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- GBF1 | c.2736G>T p.E912D (on ENST00000369983 / NM_001377137.1; = p.E911D on NM_004193.3) | Missense Mutation (SNP) | VAF 56/535 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- GNL1 | c.71G>C p.R24T | Missense Mutation (SNP) | VAF 46/642 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.95); called by muse, mutect2
- GOLGA3 | c.1445G>C p.R482P | Missense Mutation (SNP) | VAF 87/645 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- GPSM2 | c.64G>C p.A22P | Missense Mutation (SNP) | VAF 19/516 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- HAO1 | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 56/346 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- HERC2 | c.11489A>T p.Y3830F | Missense Mutation (SNP) | VAF 31/269 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- HIVEP2 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 79/515 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- HTR4 | c.5G>T p.C2F | Missense Mutation (SNP) | VAF 34/170 reads (20%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- HUWE1 | c.9466G>T p.G3156W | Missense Mutation (SNP) | VAF 58/655 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.75); called by muse, mutect2
- HUWE1 | c.3502G>C p.E1168Q | Missense Mutation (SNP) | VAF 42/558 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.537); called by muse, mutect2
- IGHV3-64 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IL1RL1 | c.150C>A p.Y50* | Nonsense Mutation (SNP) | VAF 19/420 reads (5%) | called by muse, mutect2
- INTS6 | c.2257G>T p.E753* | Nonsense Mutation (SNP) | VAF 59/323 reads (18%) | called by muse, mutect2, varscan2
- INTS6 | c.2256G>T p.M752I | Missense Mutation (SNP) | VAF 58/326 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITCH | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 44/317 reads (14%) | called by muse, varscan2
- ITPR2 | c.959C>G p.P320R | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2
- KCNJ6 | c.431T>C p.L144S | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIAA1549 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 52/392 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2D | c.10461_10466del p.S3488_Q3489del | In Frame Del (DEL) | VAF 15/148 reads (10%) | called by mutect2, pindel, varscan2
- KRT15 | c.579C>G p.L193= | Splice Region (SNP) | VAF 27/420 reads (6%) | called by muse, mutect2
- KRT38 | c.942G>T p.Q314H | Missense Mutation (SNP) | VAF 32/332 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KRTAP10-8 | c.407C>A p.S136Y | Missense Mutation (SNP) | VAF 26/563 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2
- KRTAP10-9 | c.409del p.Q137Sfs*244 | Frame Shift Del (DEL) | VAF 41/322 reads (13%) | called by mutect2, varscan2
- LIFR | c.3152A>T p.N1051I | Missense Mutation (SNP) | VAF 144/440 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- LIMA1 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 45/337 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.526C>A p.L176M | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMOD3 | c.847C>A p.H283N | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2
- LPA | c.3948T>A p.G1316= | Splice Region (SNP) | VAF 38/480 reads (8%) | called by muse, mutect2
- LRP1B | c.3853C>G p.P1285A | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- LRP2 | c.12295+1G>C p.X4099_splice | Splice Site (SNP) | VAF 19/378 reads (5%) | called by muse, mutect2
- LRP8 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 29/384 reads (8%) | called by muse, mutect2
- MAP2K7 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 40/242 reads (17%) | called by muse, mutect2, varscan2
- MAP3K4 | c.2334G>T p.W778C | Missense Mutation (SNP) | VAF 43/424 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MAP3K6 | c.1793A>T p.D598V | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MCM3 | c.1018G>C p.E340Q (on ENST00000229854 / NM_001366374.2; = p.E330Q on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.637); called by muse, mutect2
- MED12L | c.5806-1G>T p.X1936_splice | Splice Site (SNP) | VAF 21/182 reads (12%) | called by muse, varscan2
- MEIOC | c.2099T>C p.V700A | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- METTL26 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, mutect2
- MGAT3 | c.824A>G p.D275G | Missense Mutation (SNP) | VAF 19/291 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.253); called by muse, mutect2
- MMP11 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 36/321 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MON1A | c.1453G>C p.D485H | Missense Mutation (SNP) | VAF 24/493 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2
- MS4A2 | c.458A>T p.K153M | Missense Mutation (SNP) | VAF 97/652 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- MSI2 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 44/323 reads (14%) | called by muse, mutect2, varscan2
- MTMR6 | c.1394A>G p.Q465R | Missense Mutation (SNP) | VAF 56/227 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC17 | c.7135C>A p.P2379T | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- MYLK3 | c.2005C>A p.L669M | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- MYO16 | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 67/352 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYO7B | c.3500C>A p.A1167D | Missense Mutation (SNP) | VAF 39/354 reads (11%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- NAT16 | c.124T>C p.S42P | Missense Mutation (SNP) | VAF 21/233 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- NBEA | c.6060G>T p.M2020I | Missense Mutation (SNP) | VAF 64/269 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- NCOA2 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 49/265 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- NELL1 | c.1118G>T p.C373F | Missense Mutation (SNP) | VAF 66/408 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NLRP2 | c.2302G>C p.D768H | Missense Mutation (SNP) | VAF 115/790 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- NRCAM | c.580G>T p.V194F (on ENST00000379028 / NM_001371124.1; = p.V188F on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OBSCN | c.2737G>T p.E913* | Nonsense Mutation (SNP) | VAF 74/387 reads (19%) | called by muse, mutect2, varscan2
- OBSCN | c.8072A>G p.K2691R | Missense Mutation (SNP) | VAF 43/448 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.047); called by muse, mutect2
- OR11H2 | c.512C>A p.P171H (on ENST00000556246; = p.P182H on NM_001197287.1) | Missense Mutation (SNP) | VAF 111/996 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- OR13C5 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- OR2F2 | c.218A>T p.Y73F | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.844); called by muse, mutect2
- OR2F2 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR5B2 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- OSBP | c.272G>C p.R91P | Missense Mutation (SNP) | VAF 28/486 reads (6%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); called by muse, mutect2
- OTOGL | c.748A>T p.K250* (on ENST00000547103; = p.K241* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 43/351 reads (12%) | called by muse, mutect2, varscan2
- OTOGL | c.749A>T p.K250M (on ENST00000547103; = p.K241M on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/349 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- PARP9 | c.641A>C p.Q214P | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- PCDH15 | c.5094G>T p.L1698F | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- PCDH15 | c.3044T>A p.V1015E | Missense Mutation (SNP) | VAF 98/629 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PCDHA3 | c.1472C>A p.S491Y | Missense Mutation (SNP) | VAF 108/878 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PEG3 | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 31/255 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, varscan2
- PIKFYVE | c.5189C>A p.T1730K | Missense Mutation (SNP) | VAF 66/470 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1 | c.5249G>T p.G1750V | Missense Mutation (SNP) | VAF 38/740 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- PLCE1 | c.157A>T p.T53S | Missense Mutation (SNP) | VAF 105/731 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXND1 | c.3108G>T p.M1036I | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- POGLUT2 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- POGLUT2 | c.642G>T p.M214I | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.416); called by muse, mutect2
- PRKN | c.1234A>T p.K412* | Nonsense Mutation (SNP) | VAF 34/512 reads (7%) | called by muse, mutect2
- PTPN23 | c.4181C>G p.S1394C | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PUM2 | c.2543G>C p.G848A | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); called by muse, mutect2
- PUS7L | c.463A>T p.I155F | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- RAD21L1 | c.317A>C p.N106T | Missense Mutation (SNP) | VAF 78/351 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RBBP8NL | c.1010T>A p.L337Q | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- RBBP8NL | c.911A>T p.H304L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, varscan2
- RD3L | c.17G>C p.W6S | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RGPD3 | c.2260C>A p.L754I | Missense Mutation (SNP) | VAF 38/1119 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.794); called by muse, mutect2
- RGS11 | c.1088C>A p.A363D (on ENST00000397770 / NM_183337.3; = p.A342D on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF2 | c.187A>T p.T63S | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- RPE65 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 40/445 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RPS6KA5 | c.1723G>T p.D575Y | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- RTN4RL2 | c.293A>G p.Y98C | Missense Mutation (SNP) | VAF 42/477 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); called by muse, mutect2
- RUSC2 | c.962A>T p.Y321F | Missense Mutation (SNP) | VAF 61/400 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- SAMD12 | c.489G>C p.W163C | Missense Mutation (SNP) | VAF 34/639 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- SAMD9 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCN3A | c.3022G>A p.V1008I | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.057); called by muse, mutect2
- SCRN1 | c.1147A>G p.M383V | Missense Mutation (SNP) | VAF 36/324 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.007); called by muse, mutect2
- SIM2 | c.121T>G p.S41A | Missense Mutation (SNP) | VAF 72/469 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC30A10 | c.1028del p.G343Efs*36 | Frame Shift Del (DEL) | VAF 91/419 reads (22%) | called by mutect2, pindel, varscan2
- SLC38A4 | c.1624C>A p.P542T | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SLC5A1 | c.520G>T p.G174C | Missense Mutation (SNP) | VAF 57/473 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SOS1 | c.3344C>G p.S1115* | Nonsense Mutation (SNP) | VAF 24/424 reads (6%) | called by muse, mutect2
- SPANXN4 | c.256C>G p.L86V | Missense Mutation (SNP) | VAF 57/326 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- SPATA7 | c.1780G>T p.D594Y | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SPTBN2 | c.2285G>T p.W762L | Missense Mutation (SNP) | VAF 36/424 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPTBN4 | c.5116G>T p.D1706Y | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SRRM5 | c.566G>A p.R189K | Missense Mutation (SNP) | VAF 61/341 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- SRRM5 | c.765G>C p.K255N | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- STAC2 | c.696C>A p.S232R | Missense Mutation (SNP) | VAF 24/253 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.368); called by muse, mutect2
- STAM | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 28/393 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- TAF7 | c.103G>C p.G35R | Missense Mutation (SNP) | VAF 88/581 reads (15%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- TBX18 | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 48/411 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- TCL1A | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 23/270 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.345); called by muse, mutect2
- TDP2 | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 135/614 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- TDRD6 | c.1018T>C p.C340R | Missense Mutation (SNP) | VAF 29/497 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); called by muse, mutect2
- TEX44 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- TEX55 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 20/433 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.12); called by muse, mutect2
- TFAP2B | c.1147C>A p.P383T | Missense Mutation (SNP) | VAF 124/436 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM38B | c.111G>T p.P37= | Splice Region (SNP) | VAF 27/306 reads (9%) | called by muse, mutect2
- TMEM63B | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 108/448 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- TNRC18 | c.1233G>T p.Q411H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- TNS3 | c.2195C>G p.S732C | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- TRANK1 | c.8668A>T p.K2890* | Nonsense Mutation (SNP) | VAF 48/280 reads (17%) | called by muse, mutect2, varscan2
- TRAV9-1 | c.272C>G p.S91C | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRIM26 | c.343G>T p.D115Y | Missense Mutation (SNP) | VAF 89/311 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPC4 | c.1963A>T p.T655S | Missense Mutation (SNP) | VAF 111/660 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRPM3 | c.600A>T p.K200N (on ENST00000357533 / NM_001366142.2; = p.K45N on NM_020952.6) | Missense Mutation (SNP) | VAF 44/874 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2
- TRUB1 | c.642G>T p.M214I | Missense Mutation (SNP) | VAF 43/487 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.27); called by muse, mutect2
- TSKS | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2
- TUBGCP3 | c.1019C>G p.S340C | Missense Mutation (SNP) | VAF 26/393 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- UMOD | c.363C>A p.H121Q | Missense Mutation (SNP) | VAF 42/253 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USH2A | c.3214C>A p.L1072I | Missense Mutation (SNP) | VAF 131/600 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- USP24 | c.1860+1G>A p.X620_splice | Splice Site (SNP) | VAF 31/216 reads (14%) | called by muse, mutect2, varscan2
- VCAN | c.3122C>A p.T1041N | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- VCAN | c.4921G>T p.G1641C | Missense Mutation (SNP) | VAF 51/232 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VCPIP1 | c.3049G>A p.E1017K | Missense Mutation (SNP) | VAF 15/332 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.824); called by muse, mutect2
- VIRMA | c.5045A>T p.Q1682L | Missense Mutation (SNP) | VAF 14/386 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.28); called by muse, mutect2
- VN1R5 | c.438C>G p.I146M | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); called by muse, mutect2
- VSTM1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2
- WBP2 | c.186G>T p.K62N | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- WDR93 | c.1652T>G p.V551G | Missense Mutation (SNP) | VAF 67/309 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZC3HAV1 | c.385C>G p.L129V | Missense Mutation (SNP) | VAF 31/382 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZFHX4 | c.7064C>A p.A2355D | Missense Mutation (SNP) | VAF 46/321 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- ZMIZ2 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- ZNF208 | c.1075C>A p.H359N | Missense Mutation (SNP) | VAF 37/277 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF329 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF431 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 40/412 reads (10%) | called by muse, mutect2
- ZNF438 | c.207C>G p.N69K | Missense Mutation (SNP) | VAF 49/299 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF550 | c.521A>T p.Q174L | Missense Mutation (SNP) | VAF 54/410 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF560 | c.1552T>C p.C518R | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF75A | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ZP4 | c.731C>A p.T244N | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZP4 | c.367A>G p.R123G | Missense Mutation (SNP) | VAF 42/413 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2
- ZYX | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 15/377 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2
- AC098582.1 | c.2556C>T p.C852= | Silent (SNP) | VAF 22/213 reads (10%) | catalogued as rs1157264056; called by muse, mutect2, varscan2
- ADARB2 | c.2020C>A p.R674= | Silent (SNP) | VAF 48/187 reads (26%) | called by muse, mutect2, varscan2
- ALPK2 | c.3807T>C p.P1269= | Silent (SNP) | VAF 36/260 reads (14%) | called by muse, mutect2, varscan2
- AMBN | c.1239C>T p.T413= | Silent (SNP) | VAF 34/278 reads (12%) | catalogued as COSV59828152; called by muse, mutect2, varscan2
- AP4M1 | c.576C>T p.V192= | Silent (SNP) | VAF 127/813 reads (16%) | catalogued as rs776742429; called by muse, mutect2, varscan2
- APCS | c.369T>A p.I123= | Silent (SNP) | VAF 44/484 reads (9%) | called by muse, mutect2
- ASIC2 | c.351G>T p.L117= | Silent (SNP) | VAF 20/210 reads (10%) | catalogued as COSV63323622; called by muse, mutect2
- ATP5PD | c.192T>A p.A64= | Silent (SNP) | VAF 28/334 reads (8%) | called by muse, mutect2
- C20orf202 | c.276G>A p.A92= | Silent (SNP) | VAF 34/162 reads (21%) | catalogued as rs764590838, COSV68763804; called by muse, mutect2, varscan2
- CAMK2B | c.1692G>T p.G564= | Silent (SNP) | VAF 23/163 reads (14%) | called by muse, mutect2, varscan2
- CEP350 | c.5256A>G p.Q1752= | Silent (SNP) | VAF 47/459 reads (10%) | called by muse, mutect2, varscan2
- CFAP61 | c.3060T>C p.P1020= | Silent (SNP) | VAF 15/290 reads (5%) | called by muse, mutect2
- CHD9 | c.3918G>A p.L1306= | Silent (SNP) | VAF 16/236 reads (7%) | called by muse, mutect2
- CNOT4 | c.183A>G p.P61= | Silent (SNP) | VAF 22/182 reads (12%) | called by muse, mutect2, varscan2
- COL5A1 | c.3735G>T p.V1245= | Silent (SNP) | VAF 59/774 reads (8%) | catalogued as COSV65666394; called by muse, mutect2
- CPNE4 | c.618C>A p.A206= | Silent (SNP) | VAF 24/375 reads (6%) | called by muse, mutect2
- DACT1 | c.2085G>T p.R695= | Silent (SNP) | VAF 36/234 reads (15%) | called by muse, mutect2, varscan2
- DCUN1D5 | c.270G>T p.A90= | Silent (SNP) | VAF 31/306 reads (10%) | called by muse, mutect2, varscan2
- EFEMP2 | c.954C>G p.P318= | Silent (SNP) | VAF 67/469 reads (14%) | called by muse, mutect2, varscan2
- EPHB4 | c.201G>T p.P67= | Silent (SNP) | VAF 30/212 reads (14%) | catalogued as rs138656609; called by muse, mutect2, varscan2
- EPX | c.1092C>A p.R364= | Silent (SNP) | VAF 38/308 reads (12%) | catalogued as rs553342917; called by muse, mutect2, varscan2
- FAM153A | c.372A>T p.T124= | Silent (SNP) | VAF 93/388 reads (24%) | called by muse, mutect2, varscan2
- FLRT2 | c.6C>A p.G2= | Silent (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- FRMD7 | c.1848C>A p.L616= | Silent (SNP) | VAF 40/483 reads (8%) | called by muse, mutect2
- GBF1 | c.2352C>T p.R784= (on ENST00000369983 / NM_001377137.1; = p.R783= on NM_004193.3) | Silent (SNP) | VAF 22/367 reads (6%) | catalogued as rs1565168533; called by muse, mutect2
- GNB1L | c.711G>T p.L237= | Silent (SNP) | VAF 17/165 reads (10%) | called by muse, mutect2, varscan2
- GOT1 | c.843C>T p.I281= | Silent (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- GP2 | c.849C>A p.A283= (on ENST00000381362 / NM_001007240.3; = p.A280= on NM_001502.4) | Silent (SNP) | VAF 28/212 reads (13%) | catalogued as rs1299036460; called by muse, mutect2, varscan2
- GTF3C3 | c.762G>T p.L254= | Silent (SNP) | VAF 20/218 reads (9%) | called by muse, mutect2
- HAPLN4 | c.633G>T p.A211= | Silent (SNP) | VAF 24/188 reads (13%) | called by muse, mutect2, varscan2
- HLA-G | c.460C>T p.L154= | Silent (SNP) | VAF 38/736 reads (5%) | catalogued as CD984106, COSV64406193; called by muse, mutect2
- HOXA10 | c.993C>G p.L331= | Silent (SNP) | VAF 24/378 reads (6%) | catalogued as COSV52230330; called by muse, mutect2
- HOXB4 | c.567G>T p.R189= | Silent (SNP) | VAF 45/296 reads (15%) | called by muse, mutect2, varscan2
- HTR5A | c.882C>T p.F294= | Silent (SNP) | VAF 59/519 reads (11%) | catalogued as rs145653373, COSV55285251; called by muse, mutect2, varscan2
- IGKV4-1 | c.259C>A p.R87= | Silent (SNP) | VAF 43/632 reads (7%) | catalogued as rs376415297; called by muse, mutect2
- IGSF22 | c.19C>A p.R7= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV60040398; called by muse, mutect2, varscan2
- ILF2 | c.528C>T p.L176= | Silent (SNP) | VAF 23/539 reads (4%) | called by muse, mutect2
- IQSEC3 | c.1548C>A p.V516= (on ENST00000538872 / NM_001170738.2; = p.V213= on NM_015232.1) | Silent (SNP) | VAF 35/197 reads (18%) | called by muse, mutect2, varscan2
- ITCH | c.504G>T p.L168= | Silent (SNP) | VAF 42/316 reads (13%) | called by muse, varscan2
- KATNIP | c.3888G>T p.V1296= | Silent (SNP) | VAF 34/395 reads (9%) | called by muse, mutect2
- KCNIP3 | c.426G>C p.G142= | Silent (SNP) | VAF 14/216 reads (6%) | called by muse, mutect2
- KCNJ12 | c.18G>T p.R6= | Silent (SNP) | VAF 20/426 reads (5%) | catalogued as COSV59167939; called by muse, mutect2
- KEL | c.1740C>A p.A580= | Silent (SNP) | VAF 105/628 reads (17%) | catalogued as rs775099304; called by muse, mutect2, varscan2
- KLF17 | c.900C>T p.L300= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100955058; called by muse, mutect2, varscan2
- MBTPS1 | c.2928C>T p.S976= | Silent (SNP) | VAF 27/329 reads (8%) | catalogued as rs1328970325; called by muse, mutect2
- MGAT2 | c.111C>T p.L37= | Silent (SNP) | VAF 10/139 reads (7%) | catalogued as COSV100023541; called by muse, mutect2
- MRPS2 | c.789G>A p.K263= | Silent (SNP) | VAF 58/371 reads (16%) | called by muse, mutect2, varscan2
- MYBPC3 | c.3573G>A p.S1191= | Silent (SNP) | VAF 39/163 reads (24%) | catalogued as rs371488508, COSV99919970; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO7B | c.2613C>A p.A871= | Silent (SNP) | VAF 37/248 reads (15%) | catalogued as rs1254345402; called by muse, mutect2, varscan2
- NBPF4 | c.1527G>T p.L509= | Silent (SNP) | VAF 87/1002 reads (9%) | called by muse, mutect2
- NCAM1 | c.2145C>A p.P715= (on ENST00000316851 / NM_181351.5; = p.P705= on NM_000615.7) | Silent (SNP) | VAF 20/274 reads (7%) | called by muse, mutect2
- NLGN4X | c.912C>A p.V304= | Silent (SNP) | VAF 64/734 reads (9%) | catalogued as rs747131111, COSV99324248; called by muse, mutect2
- NLRP12 | c.1854C>T p.Y618= | Silent (SNP) | VAF 21/153 reads (14%) | catalogued as rs142487599; called by muse, mutect2, varscan2
- NOS1 | c.2718C>A p.T906= | Silent (SNP) | VAF 26/201 reads (13%) | catalogued as COSV57608852; called by muse, mutect2, varscan2
- NRXN1 | c.1614G>A p.V538= | Silent (SNP) | VAF 71/846 reads (8%) | called by muse, mutect2
- OR1N2 | c.813A>G p.T271= | Silent (SNP) | VAF 50/619 reads (8%) | called by muse, mutect2
- OR2T1 | c.639C>A p.V213= | Silent (SNP) | VAF 71/390 reads (18%) | called by muse, mutect2, varscan2
- OR4A16 | c.483G>T p.L161= | Silent (SNP) | VAF 66/441 reads (15%) | catalogued as rs754839912, COSV59042728; called by muse, mutect2, varscan2
- OR5AS1 | c.849C>G p.P283= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as COSV57981922; called by muse, mutect2, varscan2
- PCLO | c.3147G>T p.L1049= | Silent (SNP) | VAF 61/522 reads (12%) | called by muse, mutect2, varscan2
- PCM1 | c.5931A>T p.S1977= | Silent (SNP) | VAF 15/114 reads (13%) | called by muse, mutect2
- PDE1C | c.186A>G p.T62= | Silent (SNP) | VAF 33/230 reads (14%) | called by muse, mutect2, varscan2
- PDGFD | c.210G>T p.P70= | Silent (SNP) | VAF 73/832 reads (9%) | catalogued as COSV56381269; called by muse, mutect2
- PIWIL1 | c.1108C>A p.R370= | Silent (SNP) | VAF 19/155 reads (12%) | catalogued as COSV55343941; called by muse, mutect2, varscan2
- PNPLA5 | c.1110G>T p.P370= | Silent (SNP) | VAF 27/221 reads (12%) | catalogued as COSV53375979; called by muse, mutect2, varscan2
- POLR3A | c.4077C>G p.L1359= | Silent (SNP) | VAF 43/587 reads (7%) | called by muse, mutect2
- PRPF18 | c.63G>T p.L21= | Silent (SNP) | VAF 74/460 reads (16%) | called by muse, mutect2, varscan2
- PSG8 | c.642C>A p.P214= | Silent (SNP) | VAF 42/342 reads (12%) | called by muse, mutect2, varscan2
- RAI1 | c.3147G>T p.S1049= | Silent (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- RASAL1 | c.162G>T p.G54= | Silent (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- RGS7 | c.729C>A p.T243= | Silent (SNP) | VAF 126/590 reads (21%) | called by mutect2, varscan2
- ROBO2 | c.2790C>G p.A930= | Silent (SNP) | VAF 85/595 reads (14%) | called by muse, mutect2, varscan2
- ROR2 | c.1947G>T p.L649= | Silent (SNP) | VAF 64/890 reads (7%) | called by muse, mutect2
- RP1 | c.4308C>A p.S1436= | Silent (SNP) | VAF 32/578 reads (6%) | called by muse, mutect2
- SDK2 | c.1941T>A p.A647= | Silent (SNP) | VAF 34/297 reads (11%) | called by muse, mutect2, varscan2
- SLC38A4 | c.1056C>A p.I352= | Silent (SNP) | VAF 39/257 reads (15%) | called by muse, mutect2, varscan2
- SLC39A12 | c.1149G>T p.L383= | Silent (SNP) | VAF 48/338 reads (14%) | called by muse, mutect2, varscan2
- SLC6A19 | c.732G>T p.L244= | Silent (SNP) | VAF 44/654 reads (7%) | called by muse, mutect2
- SMTN | c.2229C>G p.A743= | Silent (SNP) | VAF 30/340 reads (9%) | called by muse, mutect2
- SPTBN2 | c.6888C>T p.F2296= | Silent (SNP) | VAF 44/656 reads (7%) | catalogued as COSV59458029; called by muse, mutect2
- STXBP3 | c.1632G>A p.V544= | Silent (SNP) | VAF 46/502 reads (9%) | catalogued as rs772238107; called by muse, mutect2
- TARS2 | c.951G>T p.L317= | Silent (SNP) | VAF 41/380 reads (11%) | called by muse, mutect2, varscan2
- TCF23 | c.132G>T p.P44= | Silent (SNP) | VAF 77/533 reads (14%) | called by muse, mutect2, varscan2
- TMEM131 | c.300C>G p.L100= | Silent (SNP) | VAF 41/307 reads (13%) | called by muse, mutect2, varscan2
- TMEM161A | c.1176C>G p.L392= | Silent (SNP) | VAF 22/295 reads (7%) | catalogued as rs1426188976, COSV50776230; called by muse, mutect2
- TRDN | c.1515A>G p.K505= | Silent (SNP) | VAF 18/187 reads (10%) | called by muse, mutect2
- TUBA4B | c.135C>A p.G45= | Silent (SNP) | VAF 25/217 reads (12%) | called by muse, mutect2, varscan2
- UBFD1 | c.213C>G p.V71= | Silent (SNP) | VAF 16/321 reads (5%) | called by muse, mutect2
- UGP2 | c.120C>G p.L40= | Silent (SNP) | VAF 16/243 reads (7%) | called by muse, mutect2
- ZIM2 | c.474C>A p.S158= | Silent (SNP) | VAF 20/226 reads (9%) | called by muse, mutect2
- ZNF287 | c.360A>T p.A120= | Silent (SNP) | VAF 23/162 reads (14%) | catalogued as COSV67689102; called by muse, mutect2, varscan2
- ZNF536 | c.159G>T p.R53= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV62828288; called by muse, mutect2, varscan2
- ZNF543 | c.1488G>A p.R496= | Silent (SNP) | VAF 17/380 reads (4%) | catalogued as rs1440120917; called by muse, mutect2
- AC011840.1 | n.1110T>C | RNA (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- ACTRT3 | chr3:169764858 G>T | 3'Flank (SNP) | VAF 17/270 reads (6%) | called by muse, mutect2
- ADAP1 | c.214-864G>T | Intron (SNP) | VAF 43/275 reads (16%) | catalogued as rs926825648; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848714 C>A | 5'Flank (SNP) | VAF 36/535 reads (7%) | catalogued as rs1350114167; called by muse, mutect2
- AL603840.1 | n.671C>A | RNA (SNP) | VAF 16/226 reads (7%) | called by muse, mutect2
- ALMS1P1 | n.838G>T | RNA (SNP) | VAF 32/392 reads (8%) | called by muse, mutect2
- ANKRD42 | chr11:83194033 G>C | 5'Flank (SNP) | VAF 43/307 reads (14%) | called by muse, mutect2, varscan2
- ARRB1 | c.21-22023G>T | Intron (SNP) | VAF 46/324 reads (14%) | called by muse, mutect2, varscan2
- BCAS3 | c.2075-5001G>A | Intron (SNP) | VAF 56/398 reads (14%) | called by muse, mutect2, varscan2
- BCAS3 | c.2075-4656G>T | Intron (SNP) | VAF 105/638 reads (16%) | called by muse, mutect2, varscan2
- C19orf25 | c.-3G>C | 5'UTR (SNP) | VAF 6/47 reads (13%) | catalogued as rs1472476979; called by muse, mutect2, varscan2
- CACNA1G | c.*138G>T | 3'UTR (SNP) | VAF 54/378 reads (14%) | called by muse, mutect2, varscan2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 4/12 reads (33%) | catalogued as rs73150876; called by mutect2, varscan2
- CD19 | c.1085-12C>A | Intron (SNP) | VAF 27/133 reads (20%) | called by muse, mutect2, varscan2
- CD300LD | chr17:74592648 T>A | 5'Flank (SNP) | VAF 40/284 reads (14%) | called by muse, mutect2, varscan2
- CELF2 | c.1076-2365G>C | Intron (SNP) | VAF 32/852 reads (4%) | called by muse, mutect2
- CHIT1 | c.*456G>T | 3'UTR (SNP) | VAF 16/453 reads (4%) | catalogued as rs1306841624; called by muse, mutect2
- CRACD | c.-2C>G | 5'UTR (SNP) | VAF 22/126 reads (17%) | called by mutect2, varscan2
- CYTH4 | c.435-696G>A | Intron (SNP) | VAF 35/534 reads (7%) | called by muse, mutect2
- DMGDH | c.*51G>C | 3'UTR (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- EPB41L3 | chr18:5630511 C>A | 5'Flank (SNP) | VAF 61/368 reads (17%) | called by muse, mutect2, varscan2
- FER1L5 | c.696+15T>A | Intron (SNP) | VAF 38/189 reads (20%) | called by muse, mutect2, varscan2
- GIMAP4 | c.58+34T>A | Intron (SNP) | VAF 34/212 reads (16%) | called by muse, mutect2, varscan2
- GORAB | c.*886G>T | 3'UTR (SNP) | VAF 29/200 reads (15%) | called by muse, mutect2, varscan2
- HSP90AB3P | n.80T>A | RNA (SNP) | VAF 55/321 reads (17%) | called by muse, mutect2, varscan2
- IKZF1 | c.161-8227C>A | Intron (SNP) | VAF 44/281 reads (16%) | called by muse, mutect2, varscan2
- IKZF1 | c.161-8226A>C | Intron (SNP) | VAF 44/280 reads (16%) | called by muse, mutect2, varscan2
- LHX6 | c.*80G>T | 3'UTR (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2
- LINC01118 | n.1191+382A>T | Intron (SNP) | VAF 18/178 reads (10%) | called by muse, mutect2, varscan2
- LINC02693 | n.685+4202G>T | Intron (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- LTBP1 | c.1034-331C>G | Intron (SNP) | VAF 24/484 reads (5%) | called by muse, mutect2
- NBPF7 | n.931G>C | RNA (SNP) | VAF 36/333 reads (11%) | called by muse, mutect2, varscan2
- NCF1B | n.582del | RNA (DEL) | VAF 14/53 reads (26%) | called by mutect2, varscan2
- NFKBIA | c.336+20C>T | Intron (SNP) | VAF 121/820 reads (15%) | catalogued as rs754935304; called by muse, mutect2, varscan2
- OR10AB1P | n.735T>A | RNA (SNP) | VAF 66/252 reads (26%) | called by muse, mutect2, varscan2
- OR3A4P | n.805G>T | RNA (SNP) | VAF 44/518 reads (8%) | called by muse, mutect2
- OR9Q1 | c.-15+53378A>G | Intron (SNP) | VAF 57/393 reads (15%) | catalogued as rs765683085; called by muse, mutect2, varscan2
- PDE10A | c.106+91670G>A | Intron (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- PRDM15 | c.-111G>T | 5'UTR (SNP) | VAF 17/408 reads (4%) | called by muse, mutect2
- PTGES3L-AARSD1 | c.9-15T>A | Intron (SNP) | VAF 20/210 reads (10%) | called by muse, mutect2, varscan2
- PXN | c.14-326C>T | Intron (SNP) | VAF 16/250 reads (6%) | called by muse, mutect2
- RABGAP1 | c.765+11A>T | Intron (SNP) | VAF 21/263 reads (8%) | called by muse, mutect2
- RANBP1 | c.505+152C>T | Intron (SNP) | VAF 40/343 reads (12%) | called by muse, mutect2, varscan2
- RASAL2 | c.3256-2367G>A | Intron (SNP) | VAF 16/390 reads (4%) | called by muse, mutect2
- SCFD2 | c.1562-35345G>T | Intron (SNP) | VAF 75/416 reads (18%) | called by muse, mutect2, varscan2
- SCLY | c.113+81C>T | Intron (SNP) | VAF 16/105 reads (15%) | called by muse, mutect2, varscan2
- SHKBP1 | c.141-19C>T | Intron (SNP) | VAF 80/350 reads (23%) | catalogued as rs768674876; called by muse, mutect2, varscan2
- SLC12A8 | c.737-45G>T | Intron (SNP) | VAF 18/206 reads (9%) | called by muse, mutect2
- SLC35F1 | c.-4C>A | 5'UTR (SNP) | VAF 20/226 reads (9%) | called by muse, mutect2
- SLC3A2 | chr11:62853378 C>G | 5'Flank (SNP) | VAF 24/408 reads (6%) | called by muse, mutect2
- ST8SIA2 | c.842+24G>T | Intron (SNP) | VAF 65/359 reads (18%) | called by muse, mutect2, varscan2
- SYNE1 | c.18573+13G>T | Intron (SNP) | VAF 15/348 reads (4%) | called by muse, mutect2
- TLR4 | c.*48C>T | 3'UTR (SNP) | VAF 20/283 reads (7%) | called by muse, mutect2
- TMEM198 | c.-57C>T | 5'UTR (SNP) | VAF 11/128 reads (9%) | catalogued as rs1157255531, COSV60537342; called by muse, mutect2
- TMEM44 | c.137+15G>T | Intron (SNP) | VAF 36/251 reads (14%) | catalogued as COSV56450819; called by muse, mutect2, varscan2
- TPM3 | c.244-6808G>A | Intron (SNP) | VAF 26/632 reads (4%) | called by muse, mutect2
- TPRX2P | n.408C>A | RNA (SNP) | VAF 23/244 reads (9%) | called by muse, mutect2
- Unknown | chr16:27290254 G>A | IGR (SNP) | VAF 43/255 reads (17%) | catalogued as rs1020212614; called by muse, mutect2, varscan2
- VGLL1 | c.688+127G>T | Intron (SNP) | VAF 28/129 reads (22%) | called by muse, mutect2, varscan2
- XAF1 | c.422-179G>T | Intron (SNP) | VAF 50/368 reads (14%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1132C>T | 3'UTR (SNP) | VAF 18/266 reads (7%) | catalogued as COSV54739467; called by muse, mutect2
- ZMYND8 | c.26-8598C>G | Intron (SNP) | VAF 20/386 reads (5%) | catalogued as rs943723441; called by muse, mutect2
- ZNF251 | c.-113G>T | 5'UTR (SNP) | VAF 26/412 reads (6%) | called by muse, mutect2
- ZNF619 | c.81-285T>C | Intron (SNP) | VAF 29/265 reads (11%) | called by muse, mutect2, varscan2
- ZNF829 | c.-4C>A | 5'UTR (SNP) | VAF 55/335 reads (16%) | called by muse, mutect2, varscan2
